Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5973, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5973-01A (Primary Tumor).

[page 1 of 3]
DIAGNOSIS

- (A) RIGHT NECK DISSECTION, LEVEL IV:
One lymph node, no tumor present.
- (B) LEFT NECK DISSECTION, LEVEL IV:
One lymph node, no tumor present.
- (C) LEFT NECK DISSECTION, LEVEL I:
Four lymph nodes, no tumor present.
Salivary gland, no tumor present.
- (D) LEFT NECK DISSECTION, LEVEL II "A":
Eight lymph nodes, no tumor present.
- (E) LEFT NECK DISSECTION, LEVEL II "B":
Five lymph nodes, no tumor present.
- (F) LEFT NECK DISSECTION, LEVEL III:
Six lymph nodes, no tumor present.
Vascular ectasia with congestion in one lymph node.
- (G) RIGHT NECK DISSECTION, LEVEL I:
Three lymph nodes, no tumor present.
Salivary gland, no tumor present.
- (H) RIGHT NECK DISSECTION, LEVEL II "A":
METASTATIC SQUAMOUS CARCINOMA (0.8 CM) IN ONE OF LYMPH NODE (1/9) WITH EXTRACAPSULAR EXTENSION
- (I) RIGHT NECK DISSECTION, LEVEL II "B":
Four lymph nodes, no tumor present.
- (J) RIGHT NECK DISSECTION, LEVEL III:
Eleven lymph nodes, no tumor present.
- (K) RIGHT NECK DISSECTION, LEVEL V:
Three lymph nodes, no tumor present.
- (L) RIGHT LINGUAL NERVE:
Nerve, no tumor present.
- (M) TOTAL GLOSSECTOMY:
INVASIVE SQUAMOUS CARCINOMA. MODERATE TO POORLY DIFFERENTIATED WITH PERINEURAL INVASION, margins negative for tumor.
- (N) RIGHT BASE OF TONGUE:
Skeletal muscle, no tumor present.
- (O) TEETH:
Multiple fragments of teeth (gross diagnosis only).

Entire report and diagnosis completed by [REDACTED]

[page 2 of 3]
GROSS DESCRIPTION

(A) RIGHT NECK DISSECTION LEVEL IV - One possible lymph node is identified (0.9 x 0.4 x 0.4 cm). It is trisected and submitted entirely in A. [REDACTED]

(B) LEFT NECK DISSECTION LEVEL IV - One possible lymph node (1.3 x 0.7 x 0.6 cm). Trisected and submitted entirely in B. [REDACTED]

(C) LEFT NECK DISSECTION LEVEL I - An irregular fragment of adipose tissue (6.0 x 3.0 x 2.5 cm). It is serially sectioned to reveal a salivary gland (3.5 x 2.5 x 2.3 cm) and six possible lymph nodes, ranging from 0.5 x 0.5 x 0.5 cm to 1.4 x 0.7 x 0.5 cm. The salivary gland is serially sectioned and no tumor is grossly identified.

SECTION CODE: C1, representative sections of salivary gland; C2, three possible lymph nodes; C3, one possible lymph node trisected; C4, one possible lymph node serially sectioned; C5, one possible lymph node trisected. [REDACTED]

(D) LEFT NECK DISSECTION LEVEL II "A" - Multiple possible lymph nodes ranging from 0.6 x 0.5 x 0.5 cm to 2.8 x 0.6 x 0.5 cm.

SECTION CODE: D1, three possible lymph nodes; D2, three possible lymph nodes; D3, one possible lymph node trisected; D4, one possible lymph node serially sectioned. [REDACTED]

(E) LEFT NECK DISSECTION, LEVEL II "B" - Six possible lymph nodes are identified ranging from 0.6 x 0.3 x 0.3 cm to 0.9 x 0.7 x 0.6 cm.

SECTION CODE: E1, three possible lymph nodes; E2, one possible lymph node bisected; E3, one possible lymph node bisected; E4, one possible lymph node bisected. [REDACTED]

(F) LEFT NECK DISSECTION LEVEL III - Seven possible lymph nodes are identified ranging from (0.3 x 0.3 x 0.3 cm to 1.3 x 1.0 x 0.7 cm).

SECTION CODE: F1, one possible lymph node; F2, three possible lymph nodes; F3, one possible lymph node; F4, one possible lymph node bisected; F5, one possible lymph node trisected. [REDACTED]

(G) RIGHT NECK DISSECTION LEVEL I - A tan-pink soft tissue (4.0 x 4.0 x 1.5 cm) with salivary gland (3.5 x 2.0 x 1.5 cm). Three lymph nodes are identified ranging from (0.4 x 0.4 x 0.3 cm to 1.2 x 1.0 x 1.0 cm).

SECTION CODE: G1, one lymph node trisected; G2, two lymph nodes; G3, representative section of salivary gland. [REDACTED]

(H) RIGHT NECK DISSECTION LEVEL II "A" - Adipose tissue (4.0 x 2.5 x 1.5 cm). Total nine lymph nodes are identified, ranging from (0.3 x 0.2 x 0.2 cm to 2.4 x 1.0 x 1.0 cm).

SECTION CODE: H1, H2, one lymph node serially sectioned; H3, one lymph node serially sectioned; H4, one lymph node serially sectioned; H5, one lymph node serially sectioned; H6, five lymph nodes. [REDACTED]

(I) RIGHT NECK DISSECTION LEVEL II "B" - Adipose tissue (3.0 x 2.5 x 1.0 cm). Total four lymph nodes are identified, ranging from (0.3 x 0.3 x 0.3 cm to 0.5 x 0.5 x 0.4 cm). The lymph nodes totally submitted in cassette I. [REDACTED]

(J) RIGHT NECK DISSECTION LEVEL III - Adipose tissue (3.5 x 3.0 x 1.5 cm). Total eleven lymph nodes are identified, ranging from (0.2 x 0.2 x 0.2 cm to 1.5 x 1.2 x 0.5 cm).

SECTION CODE: J1, one lymph node serially sectioned; J2, one lymph node serially sectioned; J3, four lymph nodes; J4, five lymph nodes. [REDACTED]

(K) RIGHT NECK DISSECTION LEVEL V - Adipose tissue (3.5 x 2.0 x 1.2 cm). Total three lymph nodes are identified ranging from (0.2 x 0.2 x 0.2 cm to 0.3 x 0.3 x 0.3 cm). The lymph nodes are totally submitted in cassette K. [REDACTED]

(L) RIGHT LINGUAL NERVE - A small white segment of nerve measures 0.3 x 0.3 x 0.1 cm and is submitted in toto for frozen section as L. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(M) () - A fungating mass measuring 5.0 x 5.0 x 4.0 cm. The submitted mass involves the superior mucosal margin of the specimen and infiltrates throughout the muscles except for approximately 0.5 cm from the deep margin.

[page 3 of 3]
The mucosal margin are grossly free and at least 1.0 cm from the edge of the mass. The specimen is submitted sequentially from anterior to posterior under M1-M20. [REDACTED]

(N) RIGHT BASE OF TONGUE - A soft red-tan fragment, with ink on true margin, measures 0.2 x 1.0 x 0.2 cm.

SECTION CODE: N, specimen submitted in toto for frozen section. [REDACTED]

*FS/DX: SKELETAL MUSCLE, NO TUMOR PRESENT. [REDACTED]

(O) TEETH - Multiple hemorrhagic fragment teeth measuring in aggregate 4.0 x 2.0 x 2.0 cm. The specimen is submitted for gross description only [REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

T-53000, M-80703

"Some tests reported here may have been developed and performance characteristics determined by [REDACTED] and Laboratory Medicine. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

[REDACTED] [REDACTED] [REDACTED]

Source: NCI Genomic Data Commons file 6c0bac80-ad9d-4110-a283-f227be607b01 (TCGA-CV-5973.48AE862D-22C8-40E5-A28C-F3A33F2BD8E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).